Gene-level copy-number profile of tumor specimen ALCH-B4BI-TTP1-A from ALCHEMIST case ALCH-B4BI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 73.6 years (26,875 days).
Specimen ALCH-B4BI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d14e5a57-b58d-4e28-a96e-355b2a445c3a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4BI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/5f1119ae-9895-46c4-afdf-8ee0e06ae539

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 3,115; copy number 2: 49,282; copy number 3: 5,498; copy number 4: 206; copy number 5: 173; copy number 6: 7; copy number 9: 9; copy number 12: 3; copy number 20: 51; copy number 25: 1.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:131,527,675–131,536,988, 2 genes: CCDC74A, MED15P4.
- chr5:179,859,013–179,861,283, 1 gene (within-gene range 0–2): AC008393.1.
- chr7:102,285,091–102,321,711, 2 genes: SH2B2, MIR4285.
- chr9:138,199,933–138,253,217, 2 genes: AL954642.1, FAM157B.
- chr10:6,149,623–6,152,277, 3 genes (within-gene range 0–2): RN7SKP78, MIR3155A, MIR3155B.
- chr10:42,997,563–42,997,681, 1 gene: MIR5100.
- chr11:64,784,918–64,803,241, 1 gene: MAP4K2.
- chr14:23,372,809–23,408,273, 4 genes: IL25, CMTM5, MYH6, MIR208A.
- chr14:77,474,394–77,498,816, 1 gene: ISM2.
- chr15:25,199,448–25,201,404, 2 genes (within-gene range 0–2): SNORD115-16, SNORD115-17.
- chr15:25,237,986–25,250,940, 8 genes (within-gene range 0–2): SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr19:35,030,470–35,066,571, 2 genes (within-gene range 0–2): SCN1B, HPN.
- chr21:45,405,165–45,513,720, 4 genes (within-gene range 0–2): COL18A1, COL18A1-AS2, COL18A1-AS1, MIR6815.
- chr21:45,914,296–45,919,483, 1 gene (within-gene range 0–2): AJ239328.1.
- chr22:18,846,811–18,861,049, 2 genes: AC008132.1, BCRP7.
- chr22:18,906,028–18,959,512, 5 genes: DGCR6, AC007326.4, PRODH, AC007326.5, AC007326.2.
- chr22:22,639,177–22,647,903, 2 genes: POM121L1P, GGTLC2.
- chr22:30,285,117–30,299,482, 2 genes (within-gene range 0–2): CASTOR1, AC004997.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 244 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:109,399,042–109,426,448, 1 gene, copy number 5: PSMA5.
- chr8:7,190,901–7,200,857, 2 genes, copy number 5–20: RPS3AP33, AF228730.1.
- chr11:65,823,022–68,130,518, 148 genes, copy number 5 (broad region; genes not listed).
- chr11:68,460,731–68,616,711, 3 genes, copy number 5: PPP6R3, NDUFA3P2, AP003096.1.
- chr11:69,294,151–69,704,022, 11 genes, copy number 5: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19.
- chr11:70,078,302–70,385,312, 12 genes, copy number 5–6 (within-gene range 4–6): ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2.
- chr14:34,659,564–37,172,606, 66 genes, copy number 5–20 (within-gene range 2–20) (broad region; genes not listed).
- chr22:18,733,914–18,757,906, 1 gene, copy number 25: FAM230E.

Autosomal genes at a single copy (total copy number 1): 776. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
